Surgical pathology report (de-identified scan), TCGA case TCGA-DA-A1I8, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Yale, specimen TCGA-DA-A1I8-06A (Metastatic).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

1CD-0-3

Melanoma, NOS 8720/3

Site: Skin, NOS C44.9 3/12/11 *lw*

Clinical History and Impression:

Melanoma.

77 year old white female with history of 2 recurrent melanomas in soft tissue of right upper arm. Status post resection 8.0 mm ulcerated melanoma right posterior arm (T4b N0 M0, Stage 2) in [REDACTED]. Sentinel lymph node 1 out of 5 positive. Completion of lymph node dissection with 10 lymph nodes negative. Finished one course of interferon which was stopped due to side effects.

Specimen(s) Received:

MELANOMA RIGHT POSTERIOR UPPER ARM

FINAL DIAGNOSIS

SKIN, RIGHT POSTERIOR UPPER ARM, EXCISION:

- METASTATIC MELANOMA (1.2 CM AND 0.7 CM) WITHIN SUBCUTANEOUS TISSUE AND SCAR
- MARGINS ARE NEGATIVE (SEE NOTE)

NOTE: Previous specimens () and () were reviewed. Morphologically similar tumor foci, measuring 1.2 cm and 0.7 cm, are seen within subcutaneous fat. A small aggregate of tumor cells is noted in the vicinity of smaller focus. The margins are free of tumor, although focally within 0.5 mm.

Pathologist:

M.D.

* Report Electronically Signed Out *

This electronic signature indicates that the pathologist has personally reviewed the available gross and/or microscopic material and has based the diagnosis on that evaluation.

Gross Description:

(, M.D.)

Received fresh in a container labeled by patient's name, and as "melanoma right posterior upper arm." Is an ellipse of skin measuring 7.7 x 3.2 x 1.7 cm. There is a fresh incision measuring 1.8 cm in the middle of the ellipse. The specimen is not oriented. At one of the ends of the long axis, the skin is indurated and scarred and this area measures about 1.6 cm. The resection margin is inked. The specimen is serially sectioned starting from the tip near the scarred area. Serial sectioning of the skin segment reveals a tan-white firm nodule approximately 1.4 cm from the tip near the scarred area in the subcutaneous fat and measures about 7mm. Serial sectioning also reveals a white firm nodule in the middle of the specimen on the subcutaneous fat, which measures 1.0 cm in diameter. The entire specimen is submitted in a total of 22 cassettes, starting with #1=tip near the scar and #22=opposite tip. Cassette #14 represents excess subcutaneous tissue contiguous to cassettes #13 and it does not have any skin.

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Summary of Stains Performed and Reviewed
H&E, Recut, Serial

Count
3

Summary of Tissue Submitted for Microscopic Examination

Block Detail

	# Blocks	Designation	#	Description
Part 1) MELANOMA RIGHT POSTERIOR UPPER AR	22	S	(22)	SKIN SERIAL

Source: NCI Genomic Data Commons file 9eb61b45-66fa-4a0d-aae8-6e7865068292 (TCGA-DA-A1I8.C0A87BE5-E61F-4E46-B1F5-FB0571454CE8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).